Somatic mutation profile of tumor specimen TCGA-CV-A6JE-01A (aliquot TCGA-CV-A6JE-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G2; Age at diagnosis: 78.5 years (28,658 days).
Specimen TCGA-CV-A6JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4945c680-5580-436f-be95-b971176ff59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JE-10A (Blood Derived Normal), aliquot TCGA-CV-A6JE-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e7e7546-812d-44a7-b744-39eb519f81a6

The open-access MAF lists 156 somatic variants for this specimen: 115 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 37, Nonsense Mutation 10, Frame Shift Ins 5, Frame Shift Del 5, Intron 2, Splice Site 2, In Frame Del 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.840A>T p.R280S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as CM136794, COSV52678283, COSV52782181, COSV52801834, COSV53205654; called by muse, mutect2, varscan2
- AAK1 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV101276004; called by muse, mutect2, varscan2
- ABCA1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV101037320; called by muse, mutect2, varscan2
- ACOT11 | c.620G>C p.R207T | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100650698; called by muse, mutect2, varscan2
- ADGRA3 | c.2861A>T p.E954V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV51565511; called by muse, mutect2, varscan2
- ADGRA3 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV99293508; called by muse, mutect2, varscan2
- ADGRB3 | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1434517917, COSV53259015, COSV99486145; called by muse, mutect2, varscan2
- ALDH6A1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs560772628, COSV100620922; called by muse, varscan2
- ANKRD44 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as COSV56550177; called by muse, mutect2, varscan2
- AR | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV101018827; called by muse, mutect2, varscan2
- ATP6AP1 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100870711; called by muse, mutect2, varscan2
- C1orf87 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64597130; called by muse, mutect2, varscan2
- CATSPERB | c.2778G>C p.Q926H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV99831495; called by muse, mutect2, varscan2
- CDH23 | c.6167T>C p.L2056P | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.445); catalogued as COSV99822387, COSV99823297; called by muse, mutect2
- CDKN2A | c.262del p.E88Rfs*58 | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | catalogued as rs1329443726, CM034218, CM095540, COSV58683071, COSV58683670; called by mutect2, pindel, varscan2
- CEP72 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs770068105, COSV99375047; called by muse, mutect2, varscan2
- CHD2 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs200830337, COSV100560806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIPC | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs751883736, COSV100694483; called by muse, mutect2, varscan2
- CNOT11 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99179336; called by muse, mutect2, varscan2
- COL20A1 | c.3418G>C p.E1140Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100490947; called by muse, mutect2, varscan2
- CRACR2A | c.1047-1G>T p.X349_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99365282; called by muse, mutect2
- CREBBP | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.028); catalogued as rs1020621997, COSV99270942; called by muse, mutect2, varscan2
- CRKL | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV62883957; called by muse, mutect2, varscan2
- CRY1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99150800, COSV99151025; called by muse, mutect2, varscan2
- DHX57 | c.320A>T p.N107I | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99769731; called by muse, mutect2, varscan2
- DNAJC5 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100694258; called by muse, mutect2, varscan2
- DNMT1 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100532741; called by muse, mutect2, varscan2
- DNMT3A | c.2677T>C p.W893R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53082058, COSV99263405; called by muse, mutect2, varscan2
- DTX4 | c.101T>A p.V34D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99915693; called by muse, mutect2
- DYNC1I1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100268810, COSV61468022; called by muse, mutect2
- EBF1 | c.1188C>G p.N396K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV100566092; called by muse, mutect2, varscan2
- ECT2 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99221584; called by muse, mutect2, varscan2
- EFR3A | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV99603291; called by muse, varscan2
- EIF2B4 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs770388291, COSV52006798; called by muse, mutect2, varscan2
- FAT1 | c.9011C>G p.S3004* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV101499461; called by muse, mutect2, varscan2
- FAT3 | c.6410G>T p.G2137V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968060; called by muse, mutect2, varscan2
- FLRT2 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100420714, COSV58145315; called by muse, mutect2, varscan2
- FOXJ2 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99368767; called by muse, mutect2, varscan2
- FTO | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV101150753; called by muse, mutect2, varscan2
- GBF1 | c.5131C>T p.P1711S (on ENST00000369983 / NM_001377137.1; = p.P1710S on NM_004193.3) | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890573; called by muse, mutect2, varscan2
- GCNA | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV101032603; called by muse, mutect2, varscan2
- H3C10 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as rs767895248, COSV60797289, COSV60799089; called by muse, mutect2, varscan2
- HAO1 | c.120T>A p.N40K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113260; called by muse, mutect2
- HCN4 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56084035; called by muse, mutect2, varscan2
- HOOK2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs747213341, COSV99317710; called by muse, mutect2, varscan2
- ICAM3 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV99349169; called by muse, mutect2
- IL6 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99331511; called by muse, mutect2, varscan2
- IMPG2 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99516021; called by muse, mutect2, varscan2
- KAT2B | c.839A>T p.E280V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99769590; called by muse, mutect2, varscan2
- KCNRG | c.581A>T p.Y194F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100466456; called by muse, mutect2, varscan2
- KDM6A | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as COSV65039246; called by muse, mutect2, varscan2
- KIR2DL4 | c.886C>T p.L296F (on ENST00000396284; = p.L257F on NM_001080772.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.945); catalogued as rs1432690718; called by muse, mutect2
- KLHL4 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100910011; called by muse, mutect2, varscan2
- KRT28 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV100137630; called by muse, mutect2, varscan2
- LIN9 | c.368A>C p.E123A (on ENST00000366808 / NM_001270410.2; = p.E68A on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as COSV100067758; called by muse, mutect2, varscan2
- LMOD1 | c.1019C>G p.S340* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100939226; called by muse, mutect2, varscan2
- LRCH3 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100605184; called by muse, mutect2, varscan2
- MAST2 | c.1363A>C p.K455Q | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100788500; called by muse, mutect2, varscan2
- MEF2A | c.264A>T p.L88F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573860; called by muse, mutect2, varscan2
- MTFR2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs967477031, COSV100886728; called by muse, mutect2, varscan2
- MUC16 | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs546209001, COSV67471740; called by muse, mutect2, varscan2
- MYB | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV100215022; called by muse, mutect2, varscan2
- NLN | c.693A>T p.L231F | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101114386; called by muse, varscan2
- NLN | c.694del p.E232Kfs*12 | Frame Shift Del (DEL) | VAF 18/27 reads (67%) | catalogued as COSV101114387; called by muse*, mutect2, varscan2*
- NLRP14 | c.1618C>G p.R540G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV100205215, COSV55065906; called by muse, mutect2, varscan2
- NLRP8 | c.2688T>A p.C896* | Nonsense Mutation (SNP) | VAF 43/87 reads (49%) | catalogued as COSV52588450; called by muse, mutect2, varscan2
- NUP133 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99773195; called by muse, mutect2, varscan2
- OFD1 | c.895A>T p.R299* | Nonsense Mutation (SNP) | VAF 36/50 reads (72%) | catalogued as COSV100406752, COSV100407021; called by muse, mutect2, varscan2
- OLFML2B | c.1978A>G p.K660E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99668675; called by muse, mutect2, varscan2
- PAX6 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53794445, COSV99570651; called by muse, mutect2, varscan2
- PCDH11X | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100013297, COSV53515632; called by muse, mutect2, varscan2
- PCDH8 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131904, COSV58814260; called by muse, mutect2, varscan2
- PPIL4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99481767; called by muse, mutect2, varscan2
- PRDM2 | c.1494G>C p.M498I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99342229; called by muse, mutect2, varscan2
- RFPL3 | c.881G>A p.G294D (on ENST00000249007 / NM_001098535.1; = p.G265D on NM_006604.2) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV99967176; called by muse, mutect2
- RIN3 | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99379616; called by muse, mutect2, varscan2
- RNF182 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101337931; called by muse, mutect2
- RPRD1A | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100036329; called by muse, mutect2, varscan2
- RREB1 | c.2538G>T p.E846D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100619570; called by muse, varscan2
- SEC24B | c.3055A>G p.I1019V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs745841340, COSV99493964; called by muse, mutect2, varscan2
- SHANK1 | c.640+1G>A p.X214_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99521629; called by muse, mutect2, varscan2
- SIGLEC9 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99142868; called by muse, mutect2, varscan2
- SLC2A4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 77/397 reads (19%) | catalogued as COSV50300975; called by muse, mutect2, varscan2
- SLC4A8 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 44/133 reads (33%) | catalogued as COSV100177212; called by muse, mutect2, varscan2
- SNRNP35 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100644579; called by muse, mutect2, varscan2
- SOCS2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500072; called by muse, mutect2, varscan2
- SPA17 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV99907197; called by muse, mutect2, varscan2
- STX5 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99587000; called by muse, varscan2
- SYNE2 | c.7048A>T p.K2350* | Nonsense Mutation (SNP) | VAF 143/220 reads (65%) | catalogued as COSV100648134; called by muse, mutect2, varscan2
- TEP1 | c.6694C>T p.H2232Y | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.673); catalogued as COSV99402842; called by muse, mutect2, varscan2
- TRAPPC2L | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs957732930, COSV99243334; called by muse, mutect2, varscan2
- TRRAP | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100722678; called by muse, mutect2
- UFL1 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.568); catalogued as COSV100990105; called by muse, mutect2
- USH1G | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100140552; called by muse, mutect2, varscan2
- YTHDF2 | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 56/173 reads (32%) | catalogued as COSV100863813; called by muse, mutect2, varscan2
- YTHDF2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370101470; called by muse, mutect2, varscan2
- ZBTB8A | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV100331433; called by muse, mutect2, varscan2
- ZDHHC19 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs751373245, COSV56348495; called by muse, mutect2, varscan2
- ZNF189 | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs200753298; called by muse, mutect2, varscan2
- ZNF25 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV100224700; called by muse, mutect2
- ZNF326 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1455329724, COSV100438213; called by muse, mutect2, varscan2
- ZNF711 | c.1843A>G p.K615E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV99341358; called by muse, mutect2, varscan2
- ZNF718 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV101210266; called by muse, mutect2, varscan2
- ZNF770 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100696010; called by muse, mutect2, varscan2
- ZNHIT2 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.188); catalogued as COSV99659383; called by muse, mutect2, varscan2
- DUSP16 | c.909dup p.A304Sfs*18 | Frame Shift Ins (INS) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- KLF1 | c.819del p.K274Rfs*23 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- KLHL38 | c.602_603del p.M201Sfs*6 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | called by mutect2, pindel, varscan2
- NLN | c.691_692insA p.L231Yfs*6 | Frame Shift Ins (INS) | VAF 18/27 reads (67%) | called by muse*, mutect2, varscan2*
- NTNG1 | c.1405_1407del p.N469del (on ENST00000370068 / NM_001113226.3; = p.N368del on NM_014917.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- RPL3 | c.774dup p.P259Sfs*21 | Frame Shift Ins (INS) | VAF 9/83 reads (11%) | called by mutect2, pindel, varscan2
- SYNE1 | c.22112C>T p.A7371V (on ENST00000367255 / NM_182961.4; = p.A7300V on NM_033071.3) | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TG | c.6342dup p.V2115Cfs*24 | Frame Shift Ins (INS) | VAF 487/744 reads (65%) | called by mutect2, pindel, varscan2
- TGM5 | c.1657_1660dup p.P554Qfs*18 (on ENST00000220420 / NM_201631.4; = p.P472Qfs*18 on NM_004245.4) | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- TOX4 | c.923del p.A308Dfs*25 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | called by mutect2, pindel, varscan2
- A1CF | c.540C>T p.G180= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99257013; called by muse, mutect2, varscan2
- ALDH6A1 | c.312C>G p.V104= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV100620921; called by muse, varscan2
- ARNT | c.2169G>A p.V723= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99648874; called by muse, mutect2, varscan2
- BLMH | c.1056C>G p.V352= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99913184; called by muse, mutect2, varscan2
- BLOC1S6 | c.9C>A p.V3= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99593470; called by muse, mutect2
- CREBBP | c.2985G>A p.L995= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99270941; called by muse, mutect2, varscan2
- CTSG | c.372G>A p.V124= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV99361608; called by muse, mutect2, varscan2
- DCHS1 | c.6108C>G p.L2036= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100202305; called by muse, mutect2, varscan2
- ERAP2 | c.2166C>G p.L722= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV101163782, COSV65940210; called by muse, mutect2, varscan2
- HDGFL2 | c.1599G>A p.K533= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100012355; called by muse, mutect2, varscan2
- HSPA1L | c.1389G>A p.L463= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV100989320, COSV100989414; called by muse, mutect2, varscan2
- IKZF4 | c.948G>A p.L316= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100009218; called by muse, mutect2, varscan2
- KCNK18 | c.795C>T p.I265= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100572091; called by muse, mutect2, varscan2
- LCT | c.1905C>T p.V635= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV99929905; called by muse, mutect2, varscan2
- LHX5 | c.765G>A p.P255= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV55663176; called by muse, mutect2
- LILRB5 | c.957G>C p.L319= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100300601; called by muse, mutect2
- LRP1B | c.2463C>T p.A821= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs770657509, COSV67224110; called by muse, mutect2, varscan2
- MROH8 | c.1200C>G p.L400= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99457527; called by muse, mutect2, varscan2
- MYO7A | c.1776C>A p.I592= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV101289208; called by muse, mutect2, varscan2
- MYO9A | c.4098A>G p.K1366= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV100613932; called by muse, mutect2, varscan2
- NFE2L3 | c.1476A>G p.Q492= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs756380692, COSV99283870; called by muse, mutect2, varscan2
- NIN | c.5709A>G p.Q1903= (on ENST00000382041 / NM_182946.1; = p.Q1190= on NM_016350.4) | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as COSV99814290; called by muse, mutect2, varscan2
- NPAS4 | c.2052G>C p.L684= | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as COSV100215113; called by muse, mutect2, varscan2
- OR7A5 | c.111C>G p.V37= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100457853; called by muse, mutect2, varscan2
- POLN | c.564G>A p.G188= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV101242597; called by muse, mutect2, varscan2
- PPP2R5A | c.1008C>T p.I336= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99806807; called by muse, mutect2, varscan2
- PTCHD4 | c.285C>T p.D95= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV59790977; called by muse, mutect2, varscan2
- PTOV1 | c.297C>T p.L99= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs766648202, COSV99681542; called by muse, mutect2, varscan2
- SCN11A | c.1122C>T p.L374= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as COSV100181999; called by muse, mutect2
- SLC2A5 | c.1368C>A p.I456= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV101072675; called by muse, mutect2, varscan2
- SNX21 | c.423C>T p.V141= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs141490712, COSV100701769; called by muse, mutect2
- SPTBN5 | c.8304C>G p.L2768= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100311850; called by muse, mutect2, varscan2
- TMEM268 | c.597C>G p.V199= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as COSV99938750, COSV99938818; called by muse, mutect2, varscan2
- TNRC6A | c.2607C>A p.A869= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100170282, COSV59362090; called by muse, mutect2, varscan2
- TTN | c.61506C>T p.D20502= (on ENST00000591111; = p.D13078= on NM_003319.4) | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1367041984, COSV60099031; ClinVar: likely benign; called by muse, mutect2
- UNC5B | c.2091G>T p.L697= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100101009; called by muse, mutect2, varscan2
- ZDHHC9 | c.210A>G p.V70= | Silent (SNP) | VAF 58/75 reads (77%) | catalogued as rs774412637, COSV100852263; called by muse, mutect2, varscan2
- DST | c.4297-1062G>A | Intron (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99758213; called by muse, mutect2, varscan2
- FOLH1B | n.1021C>T | RNA (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- LGALS8 | c.549+193T>G | Intron (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99436612; called by muse, mutect2, varscan2
- ZBTB3 | c.-86G>C | 5'UTR (SNP) | VAF 13/86 reads (15%) | catalogued as COSV101188990; called by muse, mutect2, varscan2
